Surgical pathology report (de-identified scan), TCGA case TCGA-G9-6329, project TCGA-PRAD (Prostate Adenocarcinoma), tissue source site Roswell Park, specimen TCGA-G9-6329-01A (Primary Tumor).

[page 1 of 2]
SPECIMENS:

A. PROSTATE

TCGA - G9 - 6329

SPECIMEN(S):

A. PROSTATE

GROSS DESCRIPTION:

A. PROSTATE

Received fresh is a 46g resected prostate measuring 5.5cm from right to left, 4.5cm from anterior to posterior, and 3.5cm from apex to base, with attached right and left seminal vesicles and vas deferens. The specimen is inked as follows: Anterior-Orange, Posterior-Black, Apex-Red, Base-Blue, Right-Green, and Left-Yellow. After removal of the apex and base, the remaining prostate weight is 29g. The specimen is serially sectioned from apex to base to reveal firm tan fibrous parenchyma. No obvious lesions or nodules are grossly identified. The attached right and left seminal vesicles are 2.5 x 1.5 x 0.8cm and 3 x 2.5 x 1cm, respectively, are sectioned to beige tan cystic tissue with no gross evidence of tumor involvement. The attached right and left segments of vas deferens are 1.3 x 0.6cm and 1.2 x 0.6cm, respectively, are sectioned to reveal firm tan tubular structure with no gross evidence of tumor involvement. A portion of the specimen is submitted for tissue procurement (Levels III-IV). The remainder of the specimen is submitted as follows:

- A1: right apex
- A2: left apex
- A3: Level I right side
- A4: Level I left side
- A5: Level II right anterior
- A6: Level II right posterior
- A7: Level II left anterior
- A8: Level II left posterior
- A9: Level III right anterior capsule
- A10: Level III right posterior capsule
- A11: Level III left anterior capsule
- A12: Level III left posterior capsule
- A13: Level IV right anterior capsule
- A14: Level IV right posterior capsule
- A15: Level IV left anterior capsule
- A16: Level IV left posterior capsule
- A17: right base with periurethral margin
- A18: left base with periurethral margin
- A19: right lateral base
- A20: left lateral base
- A21: right base
- A22: left base
- A23: right seminal vesicle and vas deferens
- A24: left seminal vesicle and vas deferens

DIAGNOSIS:

A. PROSTATE, PROSTATECTOMY:

- ADENOCARCINOMA OF PROSTATE, GLEASON SCORE 3 + 4 = 7/10, INVOLVING BOTH LOBES, CONFINED TO PROSTATE CAPSULE
- SURGICAL RESECTION MARGINS NEGATIVE FOR TUMOR
- SEMINAL VESICLE AND VAS DEFERENS, NEGATIVE FOR TUMOR
- SEE SYNOPTIC REPORT.

SYNOPTIC REPORT - PROSTATE GLAND

Specimens Involved

Specimens: A: PROSTATE

Location: Left

Right

Posterior lateral

WHO CLASSIFICATION

[page 2 of 2]
Epithelial tumors
Adenocarcinoma 8140/3
Multicentricity: Yes
Gland Involvement: 5%
Gleason Grade/Sum:: Grade 3 + 4 , Sum 7
High Grade PIN Present: Yes
Perineural Invasion: Yes
Vascular/Lymphatic Invasion: No
Seminal Vesicle Invasion: No
Periprostatic Fat Involved: No
Bladder Neck Involved: No
Margins Involvement: No
Frozen Performed: No
Post Hormonal Therapy Change: No
Lymph Nodes: No lymph nodes sampled
Other Pathologic Findings: None identified
Pathological Staging (pTNM): T 2c N x M x

CLINICAL HISTORY:

None provided.

PRE-OPERATIVE DIAGNOSIS:

Prostate cancer.

Source: NCI Genomic Data Commons file bed7e143-8e97-4b19-a83c-fd851794e67b (TCGA-G9-6329.FD7B8F28-B1EE-428E-859C-C888C459A3B0.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).